Somatic mutation profile of tumor specimen ALCH-B3BE-TTP1-A (aliquot ALCH-B3BE-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3BE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.5 years (20,988 days).
Specimen ALCH-B3BE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d7c986b-4592-41d0-b207-3d2541962ad3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3BE-NB1-A (Blood Derived Normal), aliquot ALCH-B3BE-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34b170c5-b4af-4593-b3f7-8468267f8714

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, 3'UTR 3, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 12/99 reads (12%) | catalogued as rs754135731; called by muse*, mutect2
- EPHA4 | c.1524del p.Y509Mfs*53 | Frame Shift Del (DEL) | VAF 50/354 reads (14%) | catalogued as COSV99917678; called by mutect2, pindel, varscan2
- MKI67 | c.8041G>A p.G2681S | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.747); catalogued as rs752782912; called by muse, mutect2, varscan2
- MYH3 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 47/392 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.584); catalogued as rs1309434110; called by muse, mutect2, varscan2
- MYH4 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs149818821; called by muse, mutect2, varscan2
- NTF3 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58417235; called by muse, mutect2
- TGFBR2 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.427); catalogued as rs727504292, CM054149, COSV55444676, COSV55450906; called by muse, mutect2, varscan2
- ZNF207 | c.239A>T p.Y80F | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV99052557; called by muse, mutect2, varscan2
- CACNG5 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAT2 | c.11756A>G p.N3919S | Missense Mutation (SNP) | VAF 23/598 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- HTR4 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- NOLC1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 14/270 reads (5%) | called by muse, mutect2
- TRIM69 | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- AFG3L2 | c.108C>T p.L36= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs1358104896; called by muse, mutect2
- CCDC168 | c.18453C>A p.I6151= | Silent (SNP) | VAF 48/298 reads (16%) | called by muse, mutect2, varscan2
- CDC23 | c.1386G>A p.V462= | Silent (SNP) | VAF 16/490 reads (3%) | called by muse, mutect2
- NEK8 | c.1795C>A p.R599= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as CM135090, COSV52046500; called by muse, mutect2, varscan2
- PLXNA2 | c.1897C>T p.L633= | Silent (SNP) | VAF 68/276 reads (25%) | called by muse, mutect2, varscan2
- ATG4B | c.*1408C>T | 3'UTR (SNP) | VAF 20/330 reads (6%) | catalogued as rs1485906253; called by muse, mutect2
- CSF2RA | c.*36G>A | 3'UTR (SNP) | VAF 27/582 reads (5%) | catalogued as rs144367097, COSV62625342; called by muse, mutect2
- FUS | c.*82C>G | 3'UTR (SNP) | VAF 28/917 reads (3%) | called by muse, mutect2
- HTR3A | c.-165C>T | 5'UTR (SNP) | VAF 9/188 reads (5%) | catalogued as COSV55469930; called by muse, mutect2
